Somatic mutation profile of tumor specimen MMRF_2613_2_BM_CD138pos (aliquot MMRF_2613_2_BM_CD138pos_T1_KHS5U_L16546) from MMRF case MMRF_2613, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,731 days).
Specimen MMRF_2613_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c09314b8-2090-4198-ba3d-caa1ab82aa74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2613_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2613_1_PB_WBC_C3_KHS5U_L13287; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3776659-d2c7-40aa-83ac-d22dec560b43

The open-access MAF lists 99 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 29, Silent 16, Intron 9, Frame Shift Del 4, 5'UTR 2, 5'Flank 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2
- ADRA2A | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs375615894; called by mutect2, varscan2
- BAHCC1 | c.7790G>A p.R2597H | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370135483; called by muse, mutect2, varscan2
- CCKBR | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747382508, COSV58098347, COSV58103191; called by muse, mutect2, varscan2
- DZIP1L | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104403687; called by muse, mutect2, varscan2
- ELAVL4 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as rs1259386502, COSV100836508; called by muse, mutect2, varscan2
- ERVV-1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 35/446 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs1474124625; called by muse, mutect2
- FAM47A | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV60493807, COSV60494503; called by muse, varscan2
- FBN1 | c.3476G>A p.C1159Y | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1555398524, CM154829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR171 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 42/397 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs200562228; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.145G>C p.D49H (on ENST00000354667 / NM_031243.3; = p.D37H on NM_002137.4) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61161915; called by muse, mutect2, varscan2
- HTR4 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs1392851615; called by muse, mutect2
- IGKJ5 | c.39A>T p.K13N | Missense Mutation (SNP) | VAF 36/200 reads (18%) | catalogued as rs373270263; called by muse, varscan2
- PCDHGA2 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as rs764027282; called by muse, mutect2, varscan2
- RWDD2A | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 36/231 reads (16%) | catalogued as rs376088857; called by muse, mutect2, varscan2
- ARMCX5 | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- BUD13 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK20 | c.75+4A>T | Splice Region (SNP) | VAF 36/232 reads (16%) | called by muse, mutect2, varscan2
- COL12A1 | c.8464C>T p.R2822* | Nonsense Mutation (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- COL25A1 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRISP2 | c.86del p.L29Cfs*2 | Frame Shift Del (DEL) | VAF 31/200 reads (16%) | called by mutect2, pindel, varscan2
- DCAF8 | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHA8 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- HSPA8 | c.1251T>A p.N417K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2R | c.1656T>G p.I552M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.038); called by mutect2, varscan2
- IGHE | c.508del p.E170Sfs*48 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- KANSL1L | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCND2 | c.1463C>A p.T488N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MACF1 | c.2471T>A p.L824H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- NXPE4 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 150/497 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2AJ1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- PML | c.2273_2275del p.E758del | In Frame Del (DEL) | VAF 32/134 reads (24%) | called by mutect2, varscan2
- RPS6KB1 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAP130 | c.698-2A>G p.X233_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- SYCP3 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- TCHHL1 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TEX13C | c.2562C>A p.N854K | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIP12 | c.1669A>T p.I557F | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- TXNDC5 | c.1205del p.F402Sfs*24 | Frame Shift Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel, varscan2
- WDR45 | c.489del p.H164Tfs*32 (on ENST00000376372 / NM_001029896.2; = p.H165Tfs*32 on NM_007075.3) | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- ANK1 | c.558G>A p.T186= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55884029; called by muse, mutect2, varscan2
- CXADR | c.483A>G p.K161= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- EEF1A2 | c.894T>C p.A298= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- EFEMP1 | c.963C>T p.P321= | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as rs769842736; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSTL4 | c.1561C>T p.L521= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99531271; called by muse, mutect2, varscan2
- FZD2 | c.1167C>T p.A389= | Silent (SNP) | VAF 45/234 reads (19%) | called by muse, mutect2, varscan2
- HEPH | c.2857C>T p.L953= (on ENST00000343002; = p.L686= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as COSV57975170; called by muse, mutect2, varscan2
- HSPA8 | c.1146A>G p.G382= | Silent (SNP) | VAF 76/262 reads (29%) | called by muse, mutect2, varscan2
- HSPB2 | c.336C>T p.F112= | Silent (SNP) | VAF 32/244 reads (13%) | catalogued as rs782751614, COSV99909872; called by muse, mutect2, varscan2
- IGHJ4 | c.3C>T p.Y1= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs368028316; called by muse, varscan2
- INPP5E | c.63G>A p.R21= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2
- LRSAM1 | c.1371C>T p.F457= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs571925919, COSV55938859; called by muse, mutect2, varscan2
- MRGPRE | c.642C>A p.G214= | Silent (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- SLC37A2 | c.1398C>T p.L466= | Silent (SNP) | VAF 30/256 reads (12%) | catalogued as rs370792494; called by muse, mutect2, varscan2
- TBL1X | c.486G>A p.A162= | Silent (SNP) | VAF 40/222 reads (18%) | catalogued as rs374413930; called by mutect2, varscan2
- TECPR1 | c.723C>T p.T241= | Silent (SNP) | VAF 24/150 reads (16%) | called by muse, mutect2, varscan2
- AP1G2 | c.978-23A>T | Intron (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918586 C>G | 5'Flank (SNP) | VAF 80/290 reads (28%) | catalogued as COSV62706232; called by muse, mutect2, varscan2
- BCLAF1 | c.*57T>A | 3'UTR (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- CAPRIN1 | c.*1260A>C | 3'UTR (SNP) | VAF 17/73 reads (23%) | catalogued as rs1436449225; called by muse, mutect2, varscan2
- CCNYL1 | c.*2288T>A | 3'UTR (SNP) | VAF 46/254 reads (18%) | called by muse, mutect2, varscan2
- CDK4 | c.-19-88T>G | Intron (SNP) | VAF 34/252 reads (13%) | catalogued as COSV56985953; called by muse, varscan2
- CHORDC1 | c.115-1322C>G | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- FASTKD2 | c.*665A>C | 3'UTR (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- FCHO1 | c.*5G>A | 3'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as rs200661021, COSV99406004; called by muse, mutect2, varscan2
- FOXN2 | c.*1471G>A | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- GAP43 | c.*547C>T | 3'UTR (SNP) | VAF 5/17 reads (29%) | catalogued as rs866198722; called by muse, mutect2, varscan2
- GMCL1 | c.*528C>T | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- GNG12 | c.*3175C>G | 3'UTR (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- GPC4 | c.*182A>G | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- H2AC6 | c.*29G>A | 3'UTR (SNP) | VAF 56/421 reads (13%) | catalogued as COSV58417362; called by muse, mutect2, varscan2
- HNF1B | c.*231G>A | 3'UTR (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- HPGDS | c.*134C>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- HSPA8 | c.1323+100T>C | Intron (SNP) | VAF 121/446 reads (27%) | called by muse, mutect2, varscan2
- IARS1 | c.2137+74G>A | Intron (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2
- INHBA | c.*4484G>A | 3'UTR (SNP) | VAF 7/72 reads (10%) | catalogued as rs910511830; called by muse, mutect2, varscan2
- LIFR | c.*6214G>C | 3'UTR (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- MAB21L3 | c.*1205G>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- MAGEB3 | c.*396A>C | 3'UTR (SNP) | VAF 16/111 reads (14%) | catalogued as COSV100854617; called by muse, mutect2, varscan2
- MAP1A | c.*542T>C | 3'UTR (SNP) | VAF 29/180 reads (16%) | called by muse, mutect2, varscan2
- NAT8L | c.*4072G>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as rs1353856137; called by muse, mutect2, varscan2
- NEUROG2 | c.*492G>A | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- NRXN1 | c.-236C>A | 5'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as rs918502917; called by muse, mutect2
- PCNX1 | c.*3952G>A | 3'UTR (SNP) | VAF 11/62 reads (18%) | catalogued as rs543173956; called by muse, mutect2, varscan2
- PCSK6 | c.2699+146C>T | Intron (SNP) | VAF 33/274 reads (12%) | called by muse, mutect2, varscan2
- PDE3A | c.*1813A>C | 3'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- PFKFB2 | c.*1345C>A | 3'UTR (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+1715C>T | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as rs1220750844; called by muse, mutect2, varscan2
- PRKCE | c.-224C>G | 5'UTR (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- RPS9 | c.407+305T>G | Intron (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- SERPINA4 | c.-18+82G>T | Intron (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- SH2B2 | chr7:102283860 G>A | 5'Flank (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- SLC9A9 | c.*135G>T | 3'UTR (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- SORCS2 | c.*521G>C | 3'UTR (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- SPA17 | c.*1222G>A | 3'UTR (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- SPA17 | c.*2180T>C | 3'UTR (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- TRAF5 | c.*2093G>A | 3'UTR (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*1249T>A | 3'UTR (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- WASF4P | n.1221T>G | RNA (SNP) | VAF 31/146 reads (21%) | catalogued as rs1223742453; called by muse, mutect2, varscan2
